Somatic mutation profile of tumor specimen TCGA-ET-A39T-01A (aliquot TCGA-ET-A39T-01A-11D-A19J-08) from TCGA case TCGA-ET-A39T, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 55.2 years (20,164 days).
Specimen TCGA-ET-A39T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60708e67-f172-48b9-b6dc-245cf0153c65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39T-10A (Blood Derived Normal), aliquot TCGA-ET-A39T-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3560e4fc-cd22-4771-baee-be18630eb447

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAND1 | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV73338682; called by muse, mutect2
- SPNS1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1215292527, COSV57957046; called by muse, mutect2, varscan2
- TBCCD1 | c.1642C>G p.P548A | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV58663868; called by muse, mutect2, varscan2
- THOC2 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55557176; called by muse, mutect2, varscan2
- ALK | c.2058C>T p.T686= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV66592764; called by muse, mutect2
- ANO9 | c.1011C>T p.T337= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV60452350; called by muse, mutect2
- RP1 | c.2508G>T p.P836= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV55120345, COSV55128734; called by muse, mutect2, varscan2
